Somatic mutation profile of tumor specimen TCGA-CV-A6JM-01A (aliquot TCGA-CV-A6JM-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 85.3 years (31,147 days).
Specimen TCGA-CV-A6JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9b79ef8-999b-4770-b5d3-e20567ce5aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JM-10A (Blood Derived Normal), aliquot TCGA-CV-A6JM-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38a194b1-d316-4979-bc8a-15ad1779edca

The open-access MAF lists 302 somatic variants for this specimen: 200 protein-altering or splice-affecting, 97 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 97, Nonsense Mutation 11, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 3, Intron 2, RNA 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM014696, COSV58688961, COSV58702489, COSV58705912; called by muse, mutect2, varscan2
- NOTCH1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 69/123 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53027071; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773905661, COSV57052830, COSV57053313, COSV57058609; called by muse, mutect2, varscan2
- ABCG8 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759068364, COSV99699406, COSV99700255; called by muse, mutect2, varscan2
- ACTL9 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs534855327, COSV100185547; called by muse, mutect2, varscan2
- ADCY8 | c.3449G>C p.R1150P | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654306; called by muse, mutect2, varscan2
- AL133500.1 | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0); catalogued as COSV99860475; called by muse, mutect2, varscan2
- ALX4 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs768153687, COSV100241118, COSV61327672; called by muse, mutect2, varscan2
- ANK3 | c.7429C>A p.H2477N | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); catalogued as COSV99782310; called by muse, mutect2, varscan2
- ARID4A | c.3674C>A p.S1225Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100794625; called by muse, mutect2
- ARMC5 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99192827; called by muse, mutect2, varscan2
- ASB1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99223450; called by muse, mutect2, varscan2
- ASXL2 | c.2518C>G p.L840V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs764223318, COSV55469318, COSV99711984; called by muse, mutect2, varscan2
- ATL3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1360649055, COSV100219985; called by muse, mutect2, varscan2
- ATP12A | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781024371, COSV99518463; called by muse, mutect2, varscan2
- ATP2A3 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV99989660; called by muse, mutect2, varscan2
- ATXN7L3 | c.943C>G p.L315V (on ENST00000389384 / NM_001382309.1; = p.L322V on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1488374974, COSV100116332; called by muse, mutect2, varscan2
- AXL | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV99997244; called by muse, mutect2, varscan2
- BCCIP | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99533154; called by muse, mutect2, varscan2
- BORA | c.395G>C p.R132T (on ENST00000613797; = p.R57T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV100909754; called by muse, mutect2, varscan2
- C11orf24 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100422705; called by muse, mutect2, varscan2
- C9orf40 | c.200C>G p.S67W | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100964975, COSV100964989; called by muse, varscan2
- CABIN1 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99573296, COSV99574005; called by muse, mutect2, varscan2
- CASP2 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100131258; called by muse, mutect2, varscan2
- CASP8 | c.550+2T>C p.X184_splice (on ENST00000432109 / NM_033355.3; = p.X216_splice on NM_001228.4) | Splice Site (SNP) | VAF 145/286 reads (51%) | catalogued as rs756660014, COSV51848988, COSV99965763; called by muse, mutect2, varscan2
- CC2D1A | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV100528696; called by muse, mutect2, varscan2
- CCDC39 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 148/426 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV99870620; called by muse, varscan2
- CCN5 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV99509479; called by muse, mutect2, varscan2
- CDH7 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59887317; called by muse, mutect2, varscan2
- CECR2 | c.1223G>A p.G408E (on ENST00000342247 / NM_001290047.2; = p.G225E on NM_001290046.1) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868448604, COSV99378335; called by muse, mutect2, varscan2
- CELF6 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99764168; called by muse, mutect2, varscan2
- CEP104 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100986731; called by muse, mutect2, varscan2
- CFTR | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99139701; called by muse, mutect2, varscan2
- CLTC | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV99292879; called by muse, mutect2, varscan2
- CLVS1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as COSV100370670; called by muse, mutect2, varscan2
- CNTN2 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100085468; called by muse, mutect2, varscan2
- COQ3 | c.954G>A p.W318* | Nonsense Mutation (SNP) | VAF 68/143 reads (48%) | catalogued as rs763813636, COSV54639818; called by muse, mutect2, varscan2
- CPA3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99936478; called by muse, mutect2, varscan2
- CPEB3 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV99800608; called by muse, mutect2, varscan2
- CREB3 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 60/173 reads (35%) | catalogued as COSV100148243; called by muse, mutect2, varscan2
- CRYGC | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as rs149880539; called by muse, mutect2, varscan2
- CSMD3 | c.6779C>T p.S2260L (on ENST00000297405 / NM_001363185.1; = p.S2156L on NM_052900.3) | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1223273629, COSV99847422; called by muse, mutect2, varscan2
- CTDP1 | c.2208G>A p.Q736= | Splice Region (SNP) | VAF 25/76 reads (33%) | catalogued as COSV50010192, COSV99311103; called by muse, mutect2, varscan2
- CUL3 | c.379-2A>G p.X127_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100024746; called by muse, mutect2, varscan2
- CYP2A6 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV56534928; called by muse, mutect2, varscan2
- CYP2A7 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV99394514; called by muse, mutect2
- DAW1 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100006529; called by muse, mutect2, varscan2
- DCC | c.3922C>T p.Q1308* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV101473539; called by muse, mutect2, varscan2
- DCTN5 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100266077; called by muse, mutect2, varscan2
- DDIAS | c.1519G>T p.V507F | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV100231438; called by muse, varscan2
- DDR2 | c.989G>C p.S330T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV100906847; called by muse, mutect2, varscan2
- DENND5A | c.2197C>G p.P733A | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV100065204; called by muse, mutect2, varscan2
- DTNA | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764410940, COSV51993542; called by muse, mutect2, varscan2
- EDEM2 | c.1095G>C p.E365D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.21); catalogued as COSV100993843; called by muse, mutect2, varscan2
- EGR2 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as COSV99654304; called by muse, mutect2, varscan2
- ERGIC3 | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.524); catalogued as COSV53413962, COSV99482019; called by muse, mutect2, varscan2
- ERMARD | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100824607; called by muse, mutect2, varscan2
- EXT1 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as CM163288, COSV100984129, COSV65481967; called by muse, mutect2, varscan2
- FABP4 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs771035469, COSV56269874; called by muse, mutect2, varscan2
- FBXO27 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV99494762; called by muse, mutect2
- FIG4 | c.2293G>C p.D765H | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100020252; called by muse, mutect2, varscan2
- GAB2 | c.571G>A p.E191K (on ENST00000361507 / NM_080491.3; = p.E153K on NM_012296.3) | Missense Mutation (SNP) | VAF 142/245 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100416854; called by muse, mutect2, varscan2
- GAL3ST1 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100143247, COSV58893872; called by muse, mutect2, varscan2
- GAS2L1 | c.1970C>G p.S657C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.322); catalogued as COSV99329711; called by muse, mutect2, varscan2
- GLI4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100391191; called by muse, mutect2, varscan2
- GNA13 | c.692A>T p.K231I | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV101457514; called by muse, mutect2, varscan2
- GNAL | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99304183; called by muse, mutect2, varscan2
- GNAZ | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV50740741; called by muse, mutect2, varscan2
- GON4L | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547557420, COSV99675728; called by muse, mutect2, varscan2
- GRIN3B | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312908; called by muse, mutect2, varscan2
- GRM1 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as COSV99264834, COSV99268849; called by muse, mutect2, varscan2
- GXYLT2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV101274680; called by muse, mutect2, varscan2
- HAUS4 | c.962G>T p.R321I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99247140; called by muse, mutect2, varscan2
- HDAC1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV100269676; called by muse, mutect2, varscan2
- ITGA8 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.755); catalogued as COSV65231379; called by muse, mutect2, varscan2
- ITGAV | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.302); catalogued as rs776935186, COSV99655652; called by muse, mutect2, varscan2
- ITGBL1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101095723; called by muse, mutect2, varscan2
- ITPR3 | c.7232C>A p.P2411H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs752938750, COSV100953664; called by muse, mutect2, varscan2
- KCNH5 | c.1593C>A p.D531E | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100528116; called by muse, mutect2, varscan2
- KCTD9 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.956); catalogued as rs1195548638, COSV99648837; called by muse, mutect2, varscan2
- KIF4B | c.3337A>T p.S1113C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV70527691; called by muse, varscan2
- KIF4B | c.3401A>G p.Q1134R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1183724316, COSV70527698; called by muse, varscan2
- KIFC3 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs782599223, COSV101109098; called by muse, mutect2, varscan2
- KLK1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs149251777; called by muse, mutect2, varscan2
- KMT2D | c.15475C>T p.R5159W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99985687; called by muse, mutect2, varscan2
- KPNA3 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99904365; called by muse, mutect2, varscan2
- LCA5 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs750681198, COSV63970894; called by muse, mutect2, varscan2
- LIPE | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99734401; called by muse, mutect2, varscan2
- LRP4 | c.4573G>A p.D1525N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as COSV101066885, COSV66135258; called by muse, mutect2, varscan2
- LRRC49 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53015401; called by muse, mutect2, varscan2
- M1AP | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.499); catalogued as COSV51845123; called by muse, mutect2, varscan2
- MAD2L1BP | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV100938764; called by muse, mutect2, varscan2
- MAGOH | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101012350, COSV65161083; called by muse, mutect2, varscan2
- MEAK7 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs199722035; called by muse, mutect2, varscan2
- MEPE | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100734995; called by muse, mutect2, varscan2
- MGAT4B | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777600325, COSV52977051; called by muse, mutect2, varscan2
- MIA3 | c.3304C>T p.P1102S | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100719533; called by muse, mutect2, varscan2
- MUC16 | c.33629C>T p.S11210L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101201647; called by muse, mutect2
- MYCBP2 | c.3845A>G p.D1282G (on ENST00000357337; = p.D1320G on NM_015057.5) | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs987490418, COSV100631838; called by muse, mutect2, varscan2
- MYH13 | c.5692T>C p.S1898P | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99355426; called by muse, mutect2, varscan2
- MYH6 | c.5602G>A p.D1868N | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100198199; called by muse, mutect2, varscan2
- MYO18B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751222865, COSV59126310, COSV59129122; called by muse, mutect2, varscan2
- MYPN | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100590620; called by muse, mutect2, varscan2
- MYRIP | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100219998, COSV56881670; called by muse, mutect2, varscan2
- NAALADL2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.086); catalogued as COSV101458195; called by muse, mutect2, varscan2
- NALCN | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV51933681; called by muse, mutect2, varscan2
- NCOR1 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV51960861; called by muse, mutect2, varscan2
- NEDD4L | c.1226G>A p.R409Q (on ENST00000400345 / NM_001144967.3; = p.R389Q on NM_015277.6) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1312844888, COSV99896534; called by muse, mutect2, varscan2
- NEK1 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101455884; called by muse, mutect2, varscan2
- NEUROD1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717048; called by muse, mutect2, varscan2
- NLGN1 | c.1644A>C p.K548N | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100850180; called by muse, mutect2, varscan2
- NMRAL1 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1177781107, COSV99361930; called by muse, mutect2, varscan2
- NOSTRIN | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.215); catalogued as COSV100474074; called by muse, mutect2, varscan2
- NUCB1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as COSV99618142; called by muse, mutect2, varscan2
- NUP210L | c.4882C>T p.P1628S | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.915); catalogued as COSV99669095; called by muse, varscan2
- OBSCN | c.23338C>T p.Q7780* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100805533; called by muse, mutect2, varscan2
- OGDHL | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.199); catalogued as COSV100934514; called by muse, mutect2, varscan2
- OR10G8 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.125); catalogued as COSV101461811, COSV101461880, COSV70908305; called by muse, mutect2, varscan2
- OR10K2 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV59220831, COSV59221326; called by muse, mutect2, varscan2
- OR1L4 | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99413946, COSV99413959; called by muse, mutect2, varscan2
- OR2M5 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.776); catalogued as COSV100822880, COSV63546061; called by muse, mutect2, varscan2
- OR2M5 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV100822884, COSV63545815; called by muse, mutect2, varscan2
- PAK1 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV99583948; called by muse, mutect2, varscan2
- PARPBP | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as COSV100569312; called by muse, mutect2, varscan2
- PCDH9 | c.3433C>T p.P1145S (on ENST00000377865 / NM_203487.3; = p.P1111S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/115 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV60592024; called by muse, mutect2, varscan2
- PCDHAC1 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV99169710; called by muse, mutect2, varscan2
- PCNX1 | c.2435C>T p.S812L | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99457178; called by muse, mutect2
- PGM2L1 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99995209; called by muse, mutect2, varscan2
- PIK3CA | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV99843495; called by muse, mutect2, varscan2
- PITPNC1 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084111, COSV55455070; called by muse, mutect2, varscan2
- PLEC | c.4107G>C p.Q1369H (on ENST00000322810 / NM_201380.4; = p.Q1259H on NM_000445.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100518803; called by muse, mutect2, varscan2
- PNLIPRP3 | c.462dup p.F155Ifs*2 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | catalogued as rs747767087; called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV100544517; called by muse, mutect2, varscan2
- POLR2F | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as COSV99970210; called by muse, mutect2, varscan2
- PRB2 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 436/1189 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.102); catalogued as COSV101231500, COSV66983322; called by muse, varscan2
- PRLHR | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1050331189, COSV99492954; called by muse, mutect2, varscan2
- PSG8 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV100126610, COSV60609151; called by muse, mutect2
- PUM1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928933; called by muse, mutect2, varscan2
- RASGRP2 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100818350; called by mutect2, varscan2
- RASSF2 | c.640-1G>C p.X214_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | catalogued as COSV101040934; called by muse, mutect2, varscan2
- RECQL5 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512348; called by muse, mutect2, varscan2
- RIMS2 | c.2971G>C p.D991H (on ENST00000666250 / NM_001348490.2; = p.D799H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV51660146, COSV99199575; called by muse, mutect2, varscan2
- RPA1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV99628365; called by muse, mutect2, varscan2
- SEMA4F | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.216); catalogued as rs908310635, COSV60285001; called by muse, mutect2, varscan2
- SEPTIN4 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100422168; called by muse, mutect2
- SGK2 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100414845; called by muse, mutect2, varscan2
- SHKBP1 | c.1815_1816del p.C605* | Frame Shift Del (DEL) | VAF 64/230 reads (28%) | catalogued as rs1397072034; called by pindel, varscan2
- SIDT1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1342424508, COSV99333272; called by muse, mutect2, varscan2
- SLC22A8 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1310792179, COSV100268091; called by muse, mutect2, varscan2
- SLC25A12 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV55533456, COSV99784734; called by muse, mutect2, varscan2
- SLC38A9 | c.618G>C p.L206F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV100591578; called by muse, mutect2, varscan2
- SMG1 | c.7363G>C p.E2455Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101246805, COSV101246844; called by muse, mutect2, varscan2
- SMURF2 | c.1049A>T p.Q350L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99301061; called by muse, mutect2, varscan2
- SORCS2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs543290121, COSV61184542; called by muse, mutect2, varscan2
- SPHKAP | c.4210G>C p.E1404Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV60871010, COSV60889520; called by muse, mutect2, varscan2
- SPTBN4 | c.5662G>A p.V1888M | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs201094636, COSV100152084; called by muse, mutect2, varscan2
- SREBF1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV99889462; called by muse, mutect2, varscan2
- SRRM2 | c.6620G>C p.R2207T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV99241728; called by muse, mutect2, varscan2
- STIP1 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV54180360; called by muse, mutect2, varscan2
- STRADA | c.142G>C p.E48Q (on ENST00000336174 / NM_001363786.1; = p.E11Q on NM_153335.6) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.398); catalogued as COSV99835349; called by muse, mutect2, varscan2
- SUGCT | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV100004552; called by muse, mutect2
- SYNM | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100153040; called by muse, mutect2, varscan2
- TAFA2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1240873111, COSV101353931; called by muse, mutect2, varscan2
- TECTB | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs920158178, COSV101027783; called by muse, mutect2, varscan2
- TLK2 | c.1547G>A p.R516Q (on ENST00000326270 / NM_001284333.2; = p.R494Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as rs753799200, COSV58299855; called by muse, mutect2, varscan2
- TMEFF1 | c.542A>C p.E181A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV100614995; called by muse, mutect2, varscan2
- TOGARAM1 | c.1715G>C p.R572T | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100753296, COSV61888471; called by muse, mutect2, varscan2
- TP53 | c.463_466dup p.R156Hfs*26 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | catalogued as COSV52974259, COSV53384084; called by mutect2, pindel, varscan2
- TRIM48 | c.579G>A p.R193= | Splice Region (SNP) | VAF 14/19 reads (74%) | catalogued as COSV101338355; called by muse, mutect2, varscan2
- TRIO | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100710174, COSV100710952; called by muse, mutect2, varscan2
- TRPV3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.94); catalogued as rs148302879; called by muse, mutect2, varscan2
- TSHZ3 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs1261231665, COSV99552707; called by muse, mutect2, varscan2
- UBTF | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV100256135; called by muse, mutect2, varscan2
- USP5 | c.2536G>A p.D846N (on ENST00000229268 / NM_001098536.2; = p.D823N on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV99979049; called by muse, mutect2, varscan2
- VPS36 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV100955294; called by muse, mutect2
- WDR62 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs762688861, COSV99544000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR83 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 76/471 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99664028; called by muse, mutect2, varscan2
- WDR90 | c.4819G>A p.D1607N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs371191203, COSV99554149; called by muse, mutect2, varscan2
- ZBED9 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 87/136 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101509392; called by muse, mutect2, varscan2
- ZIK1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs772757003, COSV100277661; called by muse, mutect2, varscan2
- ZNF174 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99237716; called by muse, mutect2, varscan2
- ZNF266 | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.243); catalogued as rs1334032824, COSV100749445; called by muse, mutect2, varscan2
- ZNF292 | c.7159C>G p.P2387A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100371259; called by muse, mutect2, varscan2
- ZNF32 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV100986520; called by muse, mutect2, varscan2
- ZNF407 | c.2124G>C p.K708N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99996740; called by muse, mutect2, varscan2
- ZNF486 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs548386025, COSV58719232; called by muse, mutect2, varscan2
- ZNF582 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100018951, COSV56732409; called by muse, mutect2
- ZNF668 | c.525G>C p.K175N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100336907; called by muse, mutect2
- ZNF682 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100653356; called by muse, mutect2, varscan2
- ZNF749 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as rs562343206, COSV100494495; called by muse, mutect2, varscan2
- ZNF774 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.109); catalogued as rs530118133, COSV100586467; called by muse, mutect2, varscan2
- ZNF8 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV99544553; called by muse, mutect2, varscan2
- AJUBA | c.753dup p.E253Gfs*53 | Frame Shift Ins (INS) | VAF 18/23 reads (78%) | called by mutect2, varscan2
- ATP1A3 | c.1390G>C p.E464Q (on ENST00000545399 / NM_001256214.2; = p.E451Q on NM_152296.5) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.317); called by muse, mutect2
- GOLGA6L22 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- HSPA6 | c.278_279delinsT p.P93Lfs*5 | Frame Shift Del (DEL) | VAF 58/259 reads (22%) | called by pindel, varscan2*
- IVD | c.311C>G p.S104C (on ENST00000651168; = p.S101C on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- PAPOLG | c.1042_1043del p.D348* | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- TRAV19 | c.69_77delinsATTTC p.V24Ffs*15 | Frame Shift Del (DEL) | VAF 19/25 reads (76%) | called by muse*, pindel
- AHNAK2 | c.933G>A p.Q311= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100318919; called by muse, mutect2
- ATG4D | c.1284C>T p.F428= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as COSV100470447; called by muse, mutect2, varscan2
- ATN1 | c.1617G>C p.L539= | Silent (SNP) | VAF 99/221 reads (45%) | catalogued as COSV100755958; called by muse, mutect2, varscan2
- ATP10A | c.4026G>A p.R1342= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100791532; called by muse, mutect2, varscan2
- ATP8B2 | c.1146C>T p.I382= (on ENST00000672630; = p.I349= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as COSV59248223; called by muse, mutect2, varscan2
- B4GALNT4 | c.1110C>T p.F370= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs906151615, COSV57322205; called by muse, mutect2, varscan2
- BNC2 | c.582C>T p.F194= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV101034390; called by muse, mutect2, varscan2
- CASP8 | c.309C>A p.V103= (on ENST00000432109 / NM_033355.3; = p.V135= on NM_001228.4) | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV99965950; called by muse, mutect2, varscan2
- CCDC39 | c.60G>C p.A20= | Silent (SNP) | VAF 56/423 reads (13%) | catalogued as rs761755432, COSV99870616; called by muse, varscan2
- CERS3 | c.1125C>T p.L375= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99432824; called by muse, mutect2, varscan2
- CERS4 | c.192G>A p.L64= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99250821; called by muse, mutect2, varscan2
- CHD3 | c.4389G>T p.L1463= | Silent (SNP) | VAF 46/168 reads (27%) | catalogued as rs568783199, COSV100391683; called by muse, mutect2, varscan2
- CRYBB1 | c.675G>A p.Q225= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs1393271770, COSV99316204; called by muse, mutect2, varscan2
- CSRNP2 | c.321C>T p.L107= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV99950505; called by muse, mutect2, varscan2
- CXXC1 | c.573G>A p.K191= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs533080894, COSV99497229; called by muse, varscan2
- DCAF4 | c.621G>T p.L207= | Silent (SNP) | VAF 184/439 reads (42%) | catalogued as COSV100611170; called by muse, mutect2, varscan2
- DDB1 | c.3165G>A p.Q1055= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV100074854; called by muse, mutect2, varscan2
- DDX23 | c.2130C>G p.L710= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV99975098; called by muse, mutect2, varscan2
- DENND1C | c.583C>T p.L195= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs756970545, COSV101200253, COSV67373704; called by muse, mutect2, varscan2
- DLGAP3 | c.282T>C p.P94= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1233522920, COSV99333171; called by muse, mutect2
- ECEL1 | c.2247C>G p.S749= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs371645572, COSV58812308; called by muse, mutect2, varscan2
- FANCD2 | c.1344G>A p.Q448= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV99812481; called by muse, mutect2, varscan2
- FBXL12 | c.669C>T p.I223= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs760302713, COSV56114958, COSV99928132; called by muse, mutect2, varscan2
- FLRT3 | c.388C>T p.L130= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99443130; called by muse, mutect2, varscan2
- FSCN1 | c.1320G>A p.A440= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs564738398, COSV61017614; called by muse, mutect2, varscan2
- GATB | c.1512C>T p.L504= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV56132620; called by muse, mutect2, varscan2
- GINS4 | c.267C>A p.L89= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV99394644; called by muse, mutect2, varscan2
- H3-4 | c.108G>T p.V36= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as COSV100797405; called by muse, mutect2, varscan2
- HRNR | c.2178C>T p.Y726= | Silent (SNP) | VAF 24/345 reads (7%) | catalogued as COSV100913924; called by muse, mutect2
- IGFL4 | c.273G>A p.K91= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV66619014; called by muse, mutect2, varscan2
- JUNB | c.717C>T p.F239= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1226993652, COSV100040347; called by muse, mutect2, varscan2
- KCNV1 | c.1422G>T p.R474= | Silent (SNP) | VAF 43/71 reads (61%) | catalogued as COSV99819432; called by muse, mutect2, varscan2
- KDM5B | c.2850G>T p.P950= | Silent (SNP) | VAF 69/96 reads (72%) | catalogued as COSV99351393; called by muse, mutect2, varscan2
- KEL | c.2115C>T p.L705= | Silent (SNP) | VAF 61/119 reads (51%) | catalogued as COSV62338955; called by muse, mutect2, varscan2
- KIF4B | c.3102T>C p.F1034= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV70527667; called by muse, mutect2
- KIF4B | c.3285G>A p.G1095= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1464014841, COSV70527684; called by muse, varscan2
- KLHL26 | c.1530C>T p.I510= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as COSV99963370; called by muse, mutect2, varscan2
- KLHL38 | c.210G>A p.K70= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs780659218, COSV100384575; called by muse, mutect2, varscan2
- KNTC1 | c.1764C>G p.L588= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100338806; called by muse, mutect2, varscan2
- KRT19 | c.330G>A p.V110= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV100843700; called by muse, mutect2, varscan2
- LAPTM4A | c.360C>T p.F120= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs367786313; called by muse, mutect2, varscan2
- LRRIQ1 | c.1713G>A p.E571= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101280707; called by muse, mutect2, varscan2
- MAST1 | c.4338G>A p.K1446= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99263687; called by muse, mutect2, varscan2
- MKRN3 | c.1509C>T p.F503= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV58811959; called by muse, mutect2, varscan2
- MTA2 | c.1041C>T p.I347= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV53472284; called by muse, mutect2, varscan2
- MUC5B | c.4479C>T p.V1493= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101500757; called by muse, mutect2, varscan2
- NALCN | c.909C>A p.I303= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99217665; called by muse, mutect2, varscan2
- NIPBL | c.6948A>G p.P2316= | Silent (SNP) | VAF 12/253 reads (5%) | catalogued as COSV99242626; called by muse, mutect2
- NKTR | c.1938C>T p.I646= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV99236344; called by muse, mutect2, varscan2
- NOL11 | c.366G>A p.V122= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as COSV99475295; called by muse, mutect2, varscan2
- NOL4 | c.1209T>A p.V403= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99308338; called by muse, mutect2, varscan2
- NPEPL1 | c.393C>T p.F131= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as rs760086884, COSV100622589; called by muse, mutect2, varscan2
- NPHP4 | c.1225C>T p.L409= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV65393728; called by muse, mutect2, varscan2
- NUP210L | c.4839C>A p.L1613= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV99669097; called by muse, varscan2
- OSTF1 | c.567G>A p.L189= | Silent (SNP) | VAF 43/71 reads (61%) | catalogued as COSV100653861; called by muse, mutect2, varscan2
- OTUB1 | c.660C>T p.I220= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV99736114; called by muse, mutect2, varscan2
- PAPOLA | c.660C>T p.F220= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99354639; called by muse, mutect2, varscan2
- PCDHA8 | c.1689G>A p.P563= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV65327882; called by muse, mutect2
- PCDHGA5 | c.1549C>T p.L517= | Silent (SNP) | VAF 67/241 reads (28%) | catalogued as COSV99546759; called by muse, mutect2, varscan2
- PCNX3 | c.69C>T p.F23= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100482731; called by muse, mutect2, varscan2
- PLEKHG4B | c.2724C>G p.L908= (on ENST00000283426; = p.L1264= on NM_052909.5) | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV99361038; called by muse, mutect2, varscan2
- PLXNB2 | c.4404C>T p.I1468= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs998895556, COSV100834299; called by muse, mutect2, varscan2
- PNKP | c.483G>A p.V161= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs766200823, COSV99681504; called by muse, mutect2, varscan2
- PPEF2 | c.969G>A p.K323= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV54423794; called by muse, mutect2
- PPM1G | c.1380C>T p.I460= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV100085393; called by muse, mutect2, varscan2
- PROP1 | c.357C>T p.N119= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs750799213, COSV100383787; called by muse, mutect2, varscan2
- PTOV1 | c.639C>T p.I213= | Silent (SNP) | VAF 36/330 reads (11%) | catalogued as rs1046596920, COSV55586361; called by muse, mutect2, varscan2
- RFC4 | c.930C>G p.L310= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as rs1229092445, COSV99960990; called by muse, mutect2, varscan2
- RFLNA | c.285C>T p.I95= (on ENST00000546355 / NM_001365156.1; = p.I14= on NM_181709.4) | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100133432; called by muse, mutect2, varscan2
- RNASET2 | c.534G>T p.V178= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as COSV99218678; called by muse, mutect2, varscan2
- RNLS | c.612G>A p.T204= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs780650761, COSV59293079; called by muse, mutect2, varscan2
- RPA1 | c.157C>T p.L53= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2
- RPL13 | c.15G>C p.R5= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99245374, COSV99245426; called by muse, mutect2, varscan2
- RPLP0 | c.294C>T p.I98= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99935468; called by muse, mutect2, varscan2
- SCNN1D | c.1569G>A p.Q523= (on ENST00000338555; = p.Q687= on NM_001130413.4) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100330268; called by muse, mutect2, varscan2
- SFTPA2 | c.534G>A p.V178= | Silent (SNP) | VAF 69/255 reads (27%) | catalogued as COSV100958852; called by muse, mutect2, varscan2
- SH2D5 | c.708C>T p.R236= (on ENST00000444387 / NM_001103161.2; = p.R152= on NM_001103160.2) | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs747513400, COSV100903899; called by muse, mutect2, varscan2
- SKIV2L | c.1452C>T p.P484= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs749486701, COSV64814704; called by muse, mutect2, varscan2
- SMTN | c.162C>T p.F54= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100294908; called by muse, mutect2, varscan2
- SPOCK1 | c.816C>T p.I272= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99970791; called by muse, mutect2, varscan2
- SPTBN4 | c.3609C>T p.L1203= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100152083; called by muse, mutect2, varscan2
- SUCO | c.168C>T p.F56= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs969129718, COSV99743787; called by muse, varscan2
- SV2B | c.1929C>T p.T643= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs761502738, COSV100370726, COSV100371025; called by muse, mutect2, varscan2
- SVIL | c.4662C>G p.L1554= (on ENST00000355867 / NM_021738.3; = p.L1128= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV100881538, COSV63449593; called by muse, mutect2
- TAF5L | c.1476G>A p.L492= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as rs751893033, COSV99273441, COSV99273627; called by muse, mutect2, varscan2
- TSC2 | c.2898C>T p.F966= | Silent (SNP) | VAF 55/214 reads (26%) | catalogued as COSV99555283; called by muse, mutect2, varscan2
- TUT1 | c.1572G>A p.G524= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99545591; called by muse, mutect2, varscan2
- UBAC2 | c.1034G>A p.*345= (on ENST00000403766 / NM_001144072.2; = p.*310= on NM_177967.4) | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100854080; called by muse, mutect2, varscan2
- UCMA | c.99G>A p.Q33= | Silent (SNP) | VAF 103/203 reads (51%) | catalogued as COSV101095494; called by muse, mutect2, varscan2
- USH2A | c.2694G>A p.Q898= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as rs1449508445, COSV100242507; called by muse, mutect2, varscan2
- UTP14A | c.318A>G p.Q106= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV100929008; called by muse, mutect2, varscan2
- VPS54 | c.1236C>T p.I412= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1251117117, COSV99708725; called by muse, varscan2
- VWF | c.5898C>T p.F1966= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV99780123; called by muse, mutect2, varscan2
- XPO1 | c.1323G>A p.V441= | Silent (SNP) | VAF 53/100 reads (53%) | catalogued as COSV101294316; called by muse, mutect2, varscan2
- ZBTB16 | c.333C>A p.I111= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs200027612, COSV100252118; called by muse, mutect2, varscan2
- ZMAT4 | c.327G>A p.E109= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as rs1279633244, COSV99911269; called by muse, mutect2
- ZNF835 | c.459G>A p.L153= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV101606403; called by muse, mutect2, varscan2
- AGAP7P | n.1548T>A | RNA (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2
- AP000769.3 | chr11:65503598 C>T | 5'Flank (SNP) | VAF 18/83 reads (22%) | catalogued as rs767238952; called by muse, mutect2, varscan2
- CTBP2 | c.58+11887G>A | Intron (SNP) | VAF 42/113 reads (37%) | catalogued as COSV100456898; called by muse, mutect2, varscan2
- SLC4A4 | c.254-30T>A | Intron (SNP) | VAF 92/339 reads (27%) | catalogued as COSV99142304; called by muse, mutect2, varscan2
- SNORD114-5 | n.16C>T | RNA (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
